Somatic mutation profile of tumor specimen TCGA-N5-A4RN-01A (aliquot TCGA-N5-A4RN-01A-12D-A28R-08) from TCGA case TCGA-N5-A4RN, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Age at diagnosis: 71.3 years (26,054 days).
Specimen TCGA-N5-A4RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84114c51-2d50-41ec-8b8c-1a28cff01452.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RN-10A (Blood Derived Normal), aliquot TCGA-N5-A4RN-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4be9474-9b44-4b76-9bb3-85422f16ba64

The open-access MAF lists 76 somatic variants for this specimen: 60 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 15, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, Splice Region 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 58/105 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.138-2A>G p.X46_splice | Splice Site (SNP) | VAF 22/24 reads (92%) | hotspot (GDC flag); catalogued as CS040288, COSV57317203, COSV57329667; called by muse, mutect2, varscan2
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 19/24 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1417846492; called by muse, mutect2, varscan2
- AGMO | c.1263G>T p.E421D | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100694593; called by muse, mutect2, varscan2
- APCDD1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763105125, COSV100789995; called by muse, mutect2, varscan2
- CD3E | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs774506155; called by muse, mutect2, varscan2
- CDCP2 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs138436244; called by muse, varscan2
- CDH22 | c.669C>A p.T223= | Splice Region (SNP) | VAF 7/28 reads (25%) | catalogued as COSV64836422; called by muse, mutect2
- CIBAR2 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV73320689; called by muse, mutect2, varscan2
- CNTNAP4 | c.3444A>G p.E1148= | Splice Region (SNP) | VAF 7/16 reads (44%) | catalogued as rs773269330, COSV56683827; called by muse, mutect2, varscan2
- CPOX | c.1171C>G p.R391G | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM011765, COSV51640215; called by muse, mutect2, varscan2
- DCTN2 | c.1188G>A p.M396I (on ENST00000548249 / NM_001261413.2; = p.M401I on NM_006400.4) | Missense Mutation (SNP) | VAF 59/100 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1406762020; called by muse, mutect2, varscan2
- EP400 | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as rs377727173; called by muse, varscan2
- HCFC2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1343070546, COSV57558996; called by muse, mutect2, varscan2
- IGKV2D-30 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs368396735; called by muse, mutect2, varscan2
- IMPG1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs370162508, COSV64055755; called by muse, mutect2, varscan2
- IRX2 | c.495C>G p.F165L | Missense Mutation (SNP) | VAF 52/1014 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57409940; called by muse, mutect2
- KCNK5 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403474881; called by muse, varscan2
- MUC16 | c.13664T>C p.L4555P | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.354); catalogued as rs900790086; called by muse, mutect2, varscan2
- NOTCH4 | c.3949C>T p.R1317W | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775564540, COSV66684623; called by muse, mutect2, varscan2
- NR1H3 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1160546592, COSV68008531; called by muse, mutect2, varscan2
- OR1N2 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs771531541; called by muse, mutect2, varscan2
- OR51Q1 | c.322G>T p.G108* | Nonsense Mutation (SNP) | VAF 57/95 reads (60%) | catalogued as COSV56178751; called by muse, mutect2, varscan2
- PLCL1 | c.1706C>T p.S569L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as rs761805495, COSV70822574; called by muse, mutect2, varscan2
- RAD54B | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 43/142 reads (30%) | catalogued as rs377463964; called by muse, mutect2, varscan2
- RAD54L | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.04); catalogued as COSV64336814; called by muse, mutect2, varscan2
- RCSD1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.074); catalogued as rs376910996; called by muse, mutect2
- RIPOR1 | c.3448C>T p.R1150* (on ENST00000379312 / NM_001193522.2; = p.R1146* on NM_024519.4) | Nonsense Mutation (SNP) | VAF 64/106 reads (60%) | catalogued as COSV50221325; called by muse, mutect2, varscan2
- RPS6KA6 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV53128375; called by muse, mutect2, varscan2
- SYNGAP1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1264547497, COSV99538004; called by muse, mutect2, varscan2
- TWNK | c.410G>T p.R137M | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV99272600; called by muse, mutect2
- UGT3A1 | c.1296-1G>A p.X432_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99954621; called by muse, mutect2, varscan2
- ZBTB11 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1343606818, COSV57247244; called by muse, mutect2, varscan2
- AL136295.1 | c.515A>T p.E172V | Missense Mutation (SNP) | VAF 111/273 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- BCL11A | c.262T>C p.S88P | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREBBP | c.6302T>C p.I2101T | Missense Mutation (SNP) | VAF 208/230 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DCT | c.1033T>A p.F345I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- DOP1A | c.3167G>T p.G1056V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GAST | c.222G>C p.K74N | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF14 | c.1359dup p.S454Ifs*8 | Frame Shift Ins (INS) | VAF 35/92 reads (38%) | called by mutect2, pindel, varscan2
- KIF26B | c.1964T>G p.F655C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LINGO4 | c.270C>A p.D90E | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- MAEL | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCM3 | c.844G>T p.A282S (on ENST00000229854 / NM_001366374.2; = p.A272S on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2
- MYPN | c.1320G>T p.M440I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.294); called by muse, mutect2
- PHLPP2 | c.1732C>T p.Q578* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- PPP2R5E | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PXDN | c.2800G>A p.G934S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB33A | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ROBO1 | c.3439G>A p.G1147R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- SEC23IP | c.1151_1152del p.E384Vfs*26 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by pindel, varscan2
- SLC14A2 | c.2023A>T p.M675L | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SORCS3 | c.3083T>A p.V1028D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SYNE1 | c.851A>T p.D284V (on ENST00000367255 / NM_182961.4; = p.D291V on NM_033071.3) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- TET2 | c.2172del p.H724Qfs*27 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- TOX | c.1182G>T p.R394S | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TRMT13 | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- TSFM | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF33B | c.2269A>C p.T757P | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DEPDC5 | c.1977T>C p.C659= (on ENST00000400246; = p.C728= on NM_014662.5) | Silent (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- GTF3C1 | c.2919C>T p.C973= | Silent (SNP) | VAF 88/174 reads (51%) | called by muse, mutect2, varscan2
- KLHDC2 | c.1002T>G p.V334= | Silent (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- LRRCC1 | c.1320T>G p.A440= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- MTIF2 | c.2064G>T p.T688= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- NELFCD | c.765C>T p.S255= (on ENST00000602795; = p.S237= on NM_198976.4) | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as rs778671462; called by muse, mutect2, varscan2
- OR9G1 | c.741C>A p.V247= | Silent (SNP) | VAF 37/272 reads (14%) | catalogued as COSV56450742; called by muse, mutect2, varscan2
- PTPRM | c.3801A>C p.T1267= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- SLC35G3 | c.273C>T p.G91= | Silent (SNP) | VAF 132/146 reads (90%) | catalogued as rs1302168191; called by muse, mutect2, varscan2
- SMARCA5 | c.486C>T p.T162= | Silent (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- SPTBN4 | c.6183T>C p.D2061= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- SUPT5H | c.1927C>T p.L643= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs753274930; called by muse, mutect2, varscan2
- TMPRSS4 | c.48C>G p.V16= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- ZNF680 | c.1470C>T p.Y490= | Silent (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
- ZSWIM8 | c.2793C>T p.D931= | Silent (SNP) | VAF 119/167 reads (71%) | catalogued as rs777112990; called by muse, mutect2, varscan2
- KIR3DX1 | n.237A>G | RNA (SNP) | VAF 10/62 reads (16%) | catalogued as rs1212421088, COSV55598900; called by muse, mutect2, varscan2
